Somatic mutation profile of tumor specimen TCGA-DA-A1HW-06A (aliquot TCGA-DA-A1HW-06A-11D-A19A-08) from TCGA case TCGA-DA-A1HW, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 37.2 years (13,592 days).
Specimen TCGA-DA-A1HW-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9cf6f63f-96c8-406b-8ba8-465ab715d55d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DA-A1HW-10A (Blood Derived Normal), aliquot TCGA-DA-A1HW-10A-01D-A19A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/59bbf541-4c55-4b25-82a2-20161aa355a0

The open-access MAF lists 408 somatic variants for this specimen: 258 protein-altering or splice-affecting, 137 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 231, Silent 137, Nonsense Mutation 18, Intron 6, Frame Shift Del 4, 3'UTR 4, In Frame Del 2, Splice Region 2, RNA 2, 5'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 53/101 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- SPAST | c.1121C>T p.P374L | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs1471030618, CM090377, COSV59517268; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.358A>G p.K120E | Missense Mutation (SNP) | VAF 37/71 reads (52%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912658, CM921039, COSV52676498, COSV52692352, COSV53551619, COSV53685479; ClinVar: likely pathogenic / uncertain significance / pathogenic; called by muse, mutect2, varscan2
- A2M | c.1574C>T p.S525F | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.781); catalogued as COSV59391266; called by muse, mutect2, varscan2
- ABCA13 | c.635C>T p.S212F | Missense Mutation (SNP) | VAF 82/177 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.052); catalogued as COSV70029615; called by muse, mutect2, varscan2
- ABCC10 | c.2098G>A p.E700K (on ENST00000372530 / NM_001198934.2; = p.E672K on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.372); catalogued as COSV55090576, COSV55092987; called by muse, mutect2, varscan2
- ABCC12 | c.142G>A p.D48N | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.71); PolyPhen benign (0.01); catalogued as rs537603050, COSV60911418, COSV60915765; called by muse, mutect2, varscan2
- ADAM32 | c.1631G>A p.W544* | Nonsense Mutation (SNP) | VAF 35/106 reads (33%) | catalogued as rs953022194, COSV65953226; called by muse, mutect2, varscan2
- ADAMTS20 | c.899G>A p.G300E | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated (0.15); PolyPhen probably damaging (1); catalogued as COSV67126043; called by muse, mutect2
- ADAT1 | c.1012C>T p.Q338* | Nonsense Mutation (SNP) | VAF 26/58 reads (45%) | catalogued as COSV57187479; called by muse, mutect2, varscan2
- ADCK1 | c.226C>T p.L76F | Missense Mutation (SNP) | VAF 34/137 reads (25%) | SIFT tolerated (0.71); PolyPhen benign (0.069); catalogued as COSV53085300; called by muse, mutect2, varscan2
- ADCY10 | c.3082G>A p.E1028K | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as rs745937549, COSV63244386; called by muse, mutect2, varscan2
- ADCY3 | c.533_535del p.S178del | In Frame Del (DEL) | VAF 17/41 reads (41%) | catalogued as rs762177923; called by mutect2, pindel, varscan2
- ADGRF3 | c.2746G>A p.E916K (on ENST00000311519 / NM_001145168.1; = p.E717K on NM_153835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.59); PolyPhen benign (0.01); catalogued as COSV61048992; called by muse, mutect2, varscan2
- ADGRG4 | c.5839C>T p.P1947S | Missense Mutation (SNP) | VAF 27/115 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.078); catalogued as COSV54961446; called by muse, mutect2, varscan2
- AEN | c.657C>G p.N219K | Missense Mutation (SNP) | VAF 64/98 reads (65%) | SIFT tolerated (0.5); PolyPhen benign (0.158); catalogued as COSV60429753; called by muse, varscan2
- AEN | c.685C>T p.R229W | Missense Mutation (SNP) | VAF 51/90 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs770249947, COSV100237500, COSV60429768; called by muse, varscan2
- AFP | c.661C>T p.Q221* | Nonsense Mutation (SNP) | VAF 17/70 reads (24%) | catalogued as COSV56926807; called by muse, mutect2, varscan2
- AGAP1 | c.836C>T p.S279F | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58337856; called by muse, mutect2, varscan2
- AGXT2 | c.127C>T p.H43Y | Missense Mutation (SNP) | VAF 68/189 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.133); catalogued as COSV51488241; called by muse, mutect2, varscan2
- AKAP3 | c.89G>A p.W30* | Nonsense Mutation (SNP) | VAF 99/317 reads (31%) | catalogued as COSV57413479, COSV57418310; called by muse, mutect2, varscan2
- AKAP7 | c.685C>T p.P229S | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.216); catalogued as COSV53836229; called by muse, mutect2
- ALCAM | c.1216G>A p.E406K | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as COSV60254069; called by muse, mutect2, varscan2
- AMY2A | c.1111G>A p.D371N | Missense Mutation (SNP) | VAF 18/167 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.018); catalogued as rs1461085460; called by mutect2, varscan2
- ANKRD44 | c.1574C>T p.P525L | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as rs1299195318, COSV56559495; called by muse, mutect2, varscan2
- ANXA2 | c.587G>A p.R196Q | Missense Mutation (SNP) | VAF 15/23 reads (65%) | SIFT tolerated (0.07); PolyPhen benign (0.023); catalogued as rs771090624, COSV100221830; called by muse, mutect2, varscan2
- APLF | c.713C>T p.S238L | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.036); catalogued as COSV58143985; called by muse, mutect2, varscan2
- ASB2 | c.1670G>A p.R557Q | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.806); catalogued as rs372274381, COSV100279170; called by muse, mutect2, varscan2
- ASXL3 | c.4108C>T p.P1370S | Missense Mutation (SNP) | VAF 49/148 reads (33%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.007); catalogued as rs1349869581, COSV52458378; called by muse, mutect2, varscan2
- ASZ1 | c.236G>A p.G79E | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT tolerated (0.21); PolyPhen probably damaging (1); catalogued as COSV52914669; called by muse, mutect2, varscan2
- ATP1A4 | c.1847G>A p.G616E | Missense Mutation (SNP) | VAF 37/128 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1332980474, COSV63628244, COSV63628270; called by muse, mutect2, varscan2
- B4GALNT4 | c.964C>T p.P322S | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.491); catalogued as COSV57324487; called by muse, mutect2
- BMP2 | c.679G>A p.V227M | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs780643020, COSV66579177; called by mutect2, varscan2
- BMPER | c.1898C>T p.A633V | Missense Mutation (SNP) | VAF 56/121 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV51824851; called by muse, mutect2, varscan2
- CACNA1F | c.3919C>T p.L1307F | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59906710; called by muse, mutect2, varscan2
- CACNA1G | c.4801C>T p.R1601W | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751861938, COSV61737415; called by muse, mutect2, varscan2
- CAPN13 | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 13/19 reads (68%) | SIFT tolerated (0.41); PolyPhen benign (0.049); catalogued as rs371549970; called by muse, mutect2, varscan2
- CDH18 | c.1604C>T p.P535L | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.075); catalogued as COSV56924842; called by muse, mutect2, varscan2
- CDH6 | c.95C>A p.P32Q | Missense Mutation (SNP) | VAF 37/97 reads (38%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as COSV54073929; called by muse, mutect2, varscan2
- CDHR1 | c.1901C>T p.S634F | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT tolerated (0.68); PolyPhen benign (0.007); catalogued as COSV60563195; called by muse, mutect2, varscan2
- CDR1 | c.637G>A p.G213R | Missense Mutation (SNP) | VAF 47/138 reads (34%) | SIFT tolerated (0.32); PolyPhen benign (0.031); catalogued as COSV65164470; called by muse, mutect2, varscan2
- CELF4 | c.828G>A p.M276I | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.029); catalogued as COSV58464520; called by muse, mutect2, varscan2
- CER1 | c.89T>A p.L30H | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.533); catalogued as COSV66603674; called by muse, mutect2, varscan2
- CES1 | c.547G>A p.E183K | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.725); catalogued as COSV62087914; called by muse, mutect2, varscan2
- CFHR5 | c.617G>A p.R206Q | Missense Mutation (SNP) | VAF 39/120 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs777505173, COSV56818118; called by muse, mutect2, varscan2
- CHGB | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV66761049; called by muse, mutect2, varscan2
- CLTC | c.3931C>G p.R1311G | Missense Mutation (SNP) | VAF 30/55 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.473); catalogued as COSV52252567; called by muse, mutect2, varscan2
- CNGA3 | c.1206G>A p.M402I | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as rs868852457, COSV55627781; called by muse, mutect2, varscan2
- CNOT7 | c.469C>T p.H157Y | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV63518010; called by muse, mutect2, varscan2
- CNTNAP1 | c.191G>A p.R64Q | Missense Mutation (SNP) | VAF 41/87 reads (47%) | SIFT tolerated (0.37); PolyPhen benign (0.01); catalogued as COSV52853825; called by muse, mutect2, varscan2
- COL11A1 | c.1735A>T p.R579W | Missense Mutation (SNP) | VAF 71/175 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV62195334; called by muse, mutect2, varscan2
- COL11A2 | c.1937G>A p.G646E (on ENST00000341947 / NM_080680.3; = p.G539E on NM_080679.2) | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV59501953; called by muse, mutect2, varscan2
- COPS5 | c.703C>T p.R235C | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs1378846658, COSV63474658; called by muse, mutect2, varscan2
- CP | c.503G>C p.G168A | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT tolerated (0.61); PolyPhen benign (0.013); catalogued as COSV52832012, COSV52834146; called by muse, mutect2, varscan2
- CPT1C | c.824C>T p.A275V | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT tolerated (0.93); PolyPhen benign (0.019); catalogued as COSV54917436; called by muse, mutect2, varscan2
- CRNN | c.538A>G p.S180G | Missense Mutation (SNP) | VAF 115/298 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV55122877; called by muse, mutect2, varscan2
- CTAGE1 | c.1949C>T p.P650L | Missense Mutation (SNP) | VAF 72/260 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.045); catalogued as rs1480064296, COSV66944540; called by muse, mutect2, varscan2
- CXCR2 | c.964C>T p.R322C | Missense Mutation (SNP) | VAF 49/132 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1298311873, COSV59279763; called by muse, mutect2, varscan2
- CYLC2 | c.80C>T p.S27L | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.957); catalogued as COSV100872521, COSV66336584; called by muse, mutect2, varscan2
- CYP3A5 | c.1006G>A p.D336N | Missense Mutation (SNP) | VAF 44/149 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.837); catalogued as COSV56121431; called by muse, mutect2, varscan2
- DCST1 | c.629A>G p.E210G | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV55060999; called by muse, mutect2, varscan2
- DDX24 | c.2119A>T p.K707* | Nonsense Mutation (SNP) | VAF 66/208 reads (32%) | catalogued as COSV58213076; called by muse, mutect2, varscan2
- DGKB | c.13G>A p.E5K | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.827); catalogued as COSV51779744; called by muse, mutect2, varscan2
- DHX9 | c.1897C>T p.P633S | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV62359530, COSV62361887; called by muse, mutect2, varscan2
- DKK2 | c.334C>T p.R112* | Nonsense Mutation (SNP) | VAF 50/123 reads (41%) | catalogued as rs528677483, COSV53396515, COSV53396966, COSV53400713; called by muse, mutect2, varscan2
- DMD | c.6302G>A p.R2101K | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.66); PolyPhen benign (0.012); catalogued as COSV63783597, COSV63787240; called by muse, varscan2
- DMD | c.5935G>A p.E1979K | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.053); catalogued as COSV63787255; called by mutect2, varscan2
- DNAH5 | c.11212G>A p.E3738K | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54205533, COSV99455398; called by muse, mutect2, varscan2
- DNAH5 | c.10666C>T p.P3556S | Missense Mutation (SNP) | VAF 32/152 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54221831; called by muse, mutect2, varscan2
- DOCK11 | c.5609C>T p.T1870I | Missense Mutation (SNP) | VAF 77/251 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52246786, COSV99354072; called by muse, mutect2, varscan2
- DSCAM | c.3746C>T p.P1249L | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.272); catalogued as COSV68034879; called by muse, mutect2, varscan2
- DSG3 | c.1420G>A p.G474S | Missense Mutation (SNP) | VAF 32/113 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.778); catalogued as rs935936043, COSV57129272; called by muse, mutect2, varscan2
- DST | c.21980C>T p.P7327L (on ENST00000361203 / NM_001374722.1; = p.P5000L on NM_015548.5) | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.458); catalogued as COSV55036795, COSV55037287; called by muse, mutect2, varscan2
- ENOX2 | c.665C>T p.A222V (on ENST00000338144 / NM_001382520.1; = p.A193V on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.917); catalogued as COSV57654905; called by muse, mutect2, varscan2
- EPHA5 | c.1640G>A p.G547D | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV56669639, COSV56675124; called by muse, mutect2, varscan2
- ERGIC3 | c.902C>T p.S301F | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53414888; called by muse, mutect2, varscan2
- ERMAP | c.368C>G p.S123C | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.72); catalogued as COSV60274984; called by muse, mutect2, varscan2
- EXOSC2 | c.691C>T p.R231* | Nonsense Mutation (SNP) | VAF 23/155 reads (15%) | catalogued as rs149299789; called by muse, mutect2, varscan2
- FAM217B | c.740C>T p.S247F | Missense Mutation (SNP) | VAF 38/138 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.549); catalogued as COSV62564694; called by muse, mutect2, varscan2
- FAM83B | c.1439G>A p.R480Q | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.401); catalogued as rs750088415, COSV60920984; called by muse, mutect2, varscan2
- FANCM | c.3616C>T p.Q1206* | Nonsense Mutation (SNP) | VAF 25/81 reads (31%) | catalogued as COSV57505907; called by muse, mutect2, varscan2
- FBLN1 | c.1822G>A p.E608K | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT tolerated (0.2); PolyPhen benign (0.113); catalogued as COSV59941978; called by muse, mutect2, varscan2
- FCRL1 | c.815G>A p.G272E | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV63824894; called by muse, mutect2, varscan2
- FGF12 | c.328C>T p.P110S (on ENST00000454309 / NM_021032.5; = p.P48S on NM_004113.6) | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.986); catalogued as COSV53186124; called by muse, mutect2, varscan2
- FLT3 | c.2822C>T p.S941L | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.393); catalogued as rs548609046, COSV54056383; called by muse, mutect2, varscan2
- FOXP1 | c.140G>A p.G47E | Missense Mutation (SNP) | VAF 42/242 reads (17%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.19); catalogued as COSV59527048; called by muse, mutect2, varscan2
- FYB2 | c.1712C>T p.S571F | Missense Mutation (SNP) | VAF 38/106 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); catalogued as COSV58586897; called by muse, mutect2, varscan2
- GFAP | c.113C>T p.S38F | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.694); catalogued as rs1455211354, COSV53653366; called by muse, mutect2, varscan2
- GLIS3 | c.6G>A p.M2I | Missense Mutation (SNP) | VAF 33/66 reads (50%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.275); catalogued as COSV60924047; called by muse, mutect2, varscan2
- GON4L | c.311C>T p.T104I | Missense Mutation (SNP) | VAF 52/143 reads (36%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.076); catalogued as COSV55197808; called by muse, mutect2, varscan2
- GPC5 | c.638G>A p.G213E | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.115); catalogued as rs1320902815, COSV65605066; called by muse, mutect2, varscan2
- GPRC6A | c.947A>G p.N316S | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.173); catalogued as COSV100114176, COSV59954288; called by muse, mutect2, varscan2
- GRIA4 | c.2371G>A p.D791N | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1164181744, COSV56882979; called by muse, mutect2, varscan2
- GRIN3A | c.2122C>T p.R708* | Nonsense Mutation (SNP) | VAF 22/94 reads (23%) | catalogued as COSV62453037; called by muse, varscan2
- GRM3 | c.769G>A p.D257N | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.847); catalogued as rs571579021, COSV64471709, COSV64473083; called by muse, mutect2, varscan2
- GTF2H1 | c.280G>A p.D94N | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.096); catalogued as COSV56377652, COSV56379217; called by muse, mutect2, varscan2
- H2BC9 | c.214G>A p.E72K | Missense Mutation (SNP) | VAF 41/139 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.069); catalogued as rs774215471, COSV55099788, COSV55100388; called by muse, mutect2, varscan2
- HARS2 | c.967C>T p.L323F | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs75387627, COSV51227430; called by muse, mutect2, varscan2
- HCFC1 | c.3275C>T p.T1092I | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV60076997; called by muse, mutect2, varscan2
- HDAC9 | c.2860G>A p.G954R | Missense Mutation (SNP) | VAF 82/241 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as COSV67783876; called by muse, mutect2, varscan2
- HDX | c.1594G>A p.E532K | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.081); catalogued as COSV52979494; called by muse, mutect2, varscan2
- HECTD4 | c.7235C>T p.P2412L | Missense Mutation (SNP) | VAF 37/123 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761593797, COSV66398717; called by muse, mutect2, varscan2
- HECTD4 | c.3425C>T p.P1142L | Missense Mutation (SNP) | VAF 42/125 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1167699474, COSV61177584; called by muse, mutect2, varscan2
- HECW2 | c.3992C>T p.P1331L | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53672539; called by muse, mutect2, varscan2
- HLA-DQA2 | c.203T>C p.V68A | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.047); catalogued as COSV66566567; called by muse, mutect2, varscan2
- IL10RB | c.646G>A p.E216K | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.116); catalogued as rs45469692, COSV51614580; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- INCENP | c.128G>A p.R43H | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as rs748187082, COSV53912946; called by muse, mutect2, varscan2
- IPO8 | c.1280C>T p.P427L | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as rs746641561, COSV56245167; called by muse, mutect2, varscan2
- JAKMIP2 | c.607G>A p.E203K | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV54599543, COSV54609309; called by muse, mutect2, varscan2
- KANK1 | c.854C>T p.P285L | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63213771; called by muse, mutect2, varscan2
- KCNIP3 | c.15G>A p.K5= | Splice Region (SNP) | VAF 4/11 reads (36%) | catalogued as COSV54672365; called by muse, mutect2
- KDR | c.3154G>A p.D1052N | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55759041, COSV55774714; called by muse, mutect2, varscan2
- KIAA1109 | c.4268C>A p.T1423N | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.042); catalogued as COSV52689867; called by muse, mutect2, varscan2
- KIF26B | c.2836C>T p.P946S | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.209); catalogued as COSV63652219; called by muse, mutect2, varscan2
- KLK5 | c.779C>T p.S260F | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60450919; called by muse, mutect2, varscan2
- KLRC3 | c.519G>A p.W173* | Nonsense Mutation (SNP) | VAF 14/54 reads (26%) | catalogued as COSV101122924; called by muse, mutect2, varscan2
- KLRC3 | c.395G>A p.G132D | Missense Mutation (SNP) | VAF 54/164 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1454055602, COSV67250939; called by muse, mutect2, varscan2
- KRTAP5-7 | c.223G>T p.G75W | Missense Mutation (SNP) | VAF 64/172 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.418); catalogued as rs750676913, COSV68325567; called by muse, varscan2
- LAMA2 | c.6029G>A p.G2010E | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as COSV70338934; called by muse, mutect2, varscan2
- LAMA3 | c.4651C>T p.L1551F | Missense Mutation (SNP) | VAF 41/116 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV58067856; called by muse, mutect2, varscan2
- LARP6 | c.1178C>T p.S393F | Missense Mutation (SNP) | VAF 40/81 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.395); catalogued as COSV54582304; called by muse, mutect2, varscan2
- LGR5 | c.1153G>A p.E385K | Missense Mutation (SNP) | VAF 120/394 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.009); catalogued as COSV57005515; called by muse, mutect2, varscan2
- LOXL2 | c.1619G>A p.G540E | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66692397; called by muse, mutect2, varscan2
- LPA | c.52G>A p.A18T | Missense Mutation (SNP) | VAF 55/171 reads (32%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.185); catalogued as COSV60310388; called by muse, mutect2, varscan2
- LRRC8A | c.1819C>T p.P607S | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52187686; called by muse, mutect2, varscan2
- LRRTM4 | c.217A>G p.I73V | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.173); catalogued as COSV69141808; called by muse, mutect2, varscan2
- MACF1 | c.1595T>C p.F532S | Missense Mutation (SNP) | VAF 60/207 reads (29%) | catalogued as COSV58385858; called by muse, mutect2, varscan2
- MACROD2 | c.548C>T p.P183L | Missense Mutation (SNP) | VAF 30/115 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53950914; called by muse, mutect2, varscan2
- MAN2A1 | c.1923A>G p.I641M | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.215); catalogued as COSV54857637; called by muse, mutect2, varscan2
- MAN2A1 | c.2790T>G p.H930Q | Missense Mutation (SNP) | VAF 51/90 reads (57%) | SIFT tolerated (0.3); PolyPhen benign (0.026); catalogued as COSV54854896; called by muse, mutect2, varscan2
- MAP3K19 | c.1088A>G p.N363S | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as COSV59641773; called by muse, mutect2, varscan2
- MAT2A | c.1066C>T p.R356C | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.807); catalogued as rs1558798457, COSV52090196; called by muse, mutect2, varscan2
- MAT2B | c.814C>T p.P272S | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT tolerated (0.19); PolyPhen benign (0.248); catalogued as rs77428501, COSV55201401; called by muse, mutect2, varscan2
- MAVS | c.668C>T p.P223L | Missense Mutation (SNP) | VAF 45/155 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); catalogued as COSV63927171; called by muse, mutect2, varscan2
- MEGF8 | c.788C>T p.S263F | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as COSV52099576; called by muse, mutect2, varscan2
- MPP2 | c.1031G>A p.R344Q (on ENST00000461854 / NM_001278372.2; = p.R320Q on NM_005374.5) | Missense Mutation (SNP) | VAF 67/139 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.207); catalogued as rs751973227, COSV52237512; called by muse, mutect2, varscan2
- MSLNL | c.812C>T p.S271L | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT deleterious (0.04); PolyPhen benign (0.041); catalogued as rs748176623, COSV53504836; called by mutect2, varscan2
- MUC16 | c.37595C>T p.S12532F | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0); catalogued as COSV67489576; called by muse, mutect2, varscan2
- MUC17 | c.11755C>T p.P3919S | Missense Mutation (SNP) | VAF 56/178 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.103); catalogued as rs865774883, COSV60281359; called by muse, mutect2, varscan2
- MUC17 | c.12317C>T p.P4106L | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.546); catalogued as rs780713362; called by muse, mutect2, varscan2
- MUSK | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 29/198 reads (15%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.175); catalogued as COSV51894942; called by muse, mutect2, varscan2
- MYH1 | c.4756G>A p.E1586K | Missense Mutation (SNP) | VAF 68/129 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV56852376, COSV99875531; called by muse, mutect2, varscan2
- MYO18B | c.1310G>A p.W437* | Nonsense Mutation (SNP) | VAF 4/16 reads (25%) | catalogued as COSV59146440; called by muse, mutect2
- NCR1 | c.476G>A p.G159E | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.426); catalogued as rs774857066, COSV52557516; called by muse, mutect2, varscan2
- NFASC | c.1837C>T p.Q613* | Nonsense Mutation (SNP) | VAF 11/41 reads (27%) | catalogued as COSV58378210; called by muse, mutect2, varscan2
- NFATC3 | c.532G>A p.D178N | Missense Mutation (SNP) | VAF 35/71 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV60476229; called by muse, mutect2, varscan2
- NKAPL | c.161C>T p.P54L | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV59197641; called by muse, mutect2, varscan2
- NKD1 | c.566C>T p.P189L | Missense Mutation (SNP) | VAF 24/45 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV51692528; called by muse, mutect2, varscan2
- NPC1L1 | c.1105G>A p.G369S | Missense Mutation (SNP) | VAF 37/73 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56927359; called by muse, mutect2, varscan2
- NUDT9 | c.161C>T p.S54F | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as COSV56197258; called by muse, mutect2, varscan2
- NWD1 | c.3440C>T p.S1147F | Missense Mutation (SNP) | VAF 96/191 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as rs762233189, COSV60346297; called by muse, mutect2, varscan2
- OPRL1 | c.1106C>T p.P369L | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.781); catalogued as COSV61092743; called by muse, mutect2, varscan2
- OR10A6 | c.629C>T p.P210L | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59165931; called by muse, mutect2, varscan2
- OR4K17 | c.95C>T p.S32L | Missense Mutation (SNP) | VAF 64/261 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.014); catalogued as rs150087607; called by muse, mutect2, varscan2
- OR9G1 | c.382C>T p.P128S | Missense Mutation (SNP) | VAF 19/156 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs139404745, COSV56449666; called by muse, mutect2, varscan2
- PCDH12 | c.1102C>T p.P368S | Missense Mutation (SNP) | VAF 43/99 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV51522720; called by muse, mutect2, varscan2
- PCDH15 | c.4651G>A p.E1551K (on ENST00000644397 / NM_001354429.2; = p.E1500K on NM_001142769.3) | Missense Mutation (SNP) | VAF 56/122 reads (46%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.477); catalogued as COSV64688489; called by muse, mutect2, varscan2
- PCDH15 | c.2185G>A p.E729K | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV57348774; called by muse, mutect2, varscan2
- PCDHGB3 | c.164G>A p.G55E | Missense Mutation (SNP) | VAF 51/116 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); catalogued as rs1191020056, COSV54019750; called by muse, mutect2, varscan2
- PCDHGB5 | c.1190C>T p.S397L | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.009); catalogued as rs368407532, COSV53973969; called by muse, mutect2, varscan2
- PEG3 | c.116C>T p.P39L | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.154); catalogued as COSV55639554; called by muse, mutect2, varscan2
- PGK1 | c.407C>T p.S136F | Missense Mutation (SNP) | VAF 167/456 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as COSV64832410; called by muse, mutect2, varscan2
- PITPNM1 | c.1405C>T p.P469S | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs928901331, COSV62709709; called by muse, mutect2
- PITRM1 | c.805G>A p.G269S | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1442467139, COSV56533161; called by muse, mutect2, varscan2
- PLCL1 | c.1081G>A p.E361K | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1357149217, COSV70821581; called by muse, mutect2, varscan2
- PLEKHG6 | c.587G>A p.R196Q | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.993); catalogued as rs763094421, COSV50610713; called by mutect2, varscan2
- PPARG | c.254G>A p.R85K (on ENST00000287820 / NM_015869.5; = p.R55K on NM_005037.7) | Missense Mutation (SNP) | VAF 199/402 reads (50%) | SIFT tolerated, low confidence (0.84); PolyPhen benign (0.281); catalogued as rs1196196054, COSV55145095; called by muse, mutect2, varscan2
- PRAMEF12 | c.236G>A p.R79Q | Missense Mutation (SNP) | VAF 32/111 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs769755107, COSV63214663; called by muse, mutect2, varscan2
- PRKACG | c.493C>T p.H165Y | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55256697; called by muse, mutect2, varscan2
- PRKCI | c.943C>T p.L315F | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55520612; called by muse, mutect2, varscan2
- PRRC2C | c.2906C>T p.P969L (on ENST00000367742; = p.P967L on NM_015172.4) | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV58912108; called by muse, mutect2, varscan2
- PRSS16 | c.224G>A p.R75Q | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.071); catalogued as rs150849072; called by muse, mutect2
- PRSS37 | c.646G>A p.G216S | Missense Mutation (SNP) | VAF 35/159 reads (22%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.988); catalogued as rs756834067, COSV63339731; called by muse, mutect2, varscan2
- PXDNL | c.1388G>A p.G463D | Missense Mutation (SNP) | VAF 35/111 reads (32%) | SIFT tolerated (0.63); PolyPhen benign (0.101); catalogued as rs1464879941, COSV62497258; called by muse, mutect2, varscan2
- PZP | c.3414G>A p.W1138* | Nonsense Mutation (SNP) | VAF 28/86 reads (33%) | catalogued as rs780631587, COSV54358507, COSV54364704; called by muse, mutect2, varscan2
- REPS1 | c.1732_1745del p.A578Pfs*33 (on ENST00000450536 / NM_001286611.2; = p.A577Pfs*33 on NM_031922.4) | Frame Shift Del (DEL) | VAF 12/74 reads (16%) | catalogued as COSV57812303; called by mutect2, pindel, varscan2
- RIMS2 | c.3328C>T p.P1110S (on ENST00000666250 / NM_001348490.2; = p.P918S on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs980162989; called by muse, mutect2, varscan2
- RIN3 | c.1058C>T p.P353L | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.457); catalogued as rs1319518337, COSV53654740; called by muse, mutect2, varscan2
- RNF17 | c.1082C>T p.P361L | Missense Mutation (SNP) | VAF 73/237 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV55045199; called by muse, mutect2, varscan2
- RNF31 | c.797A>T p.H266L | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as COSV53761095; called by muse, mutect2, varscan2
- RPUSD1 | c.543T>G p.S181R | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); catalogued as COSV50102263; called by muse, mutect2, varscan2
- RTN1 | c.1034C>T p.S345F | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.459); catalogued as COSV50744425; called by muse, mutect2, varscan2
- RTN3 | c.718G>A p.E240K (on ENST00000377819 / NM_001265589.2; = p.E221K on NM_201428.3) | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV58031791; called by muse, mutect2, varscan2
- RXFP2 | c.1681G>A p.D561N | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.022); catalogued as rs867037646, COSV53638767; called by muse, mutect2, varscan2
- RYR2 | c.8717G>A p.G2906E | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.338); catalogued as COSV63668312, COSV63710244; called by muse, mutect2, varscan2
- RYR3 | c.6476T>G p.L2159R | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66806428; called by muse, mutect2, varscan2
- SAMSN1 | c.293G>A p.G98E | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT tolerated (0.42); PolyPhen benign (0.019); catalogued as rs1285816485, COSV53476561; called by muse, mutect2, varscan2
- SART3 | c.2837C>T p.P946L (on ENST00000228284; = p.P928L on NM_014706.4) | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.037); catalogued as COSV57208752; called by muse, mutect2, varscan2
- SCML2 | c.1714G>A p.D572N | Missense Mutation (SNP) | VAF 42/141 reads (30%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV52622960; called by muse, mutect2, varscan2
- SCN7A | c.3289C>T p.P1097S | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.57); PolyPhen benign (0.015); catalogued as rs1280223421, COSV69274310; called by muse, mutect2, varscan2
- SEPTIN6 | c.610G>A p.E204K | Missense Mutation (SNP) | VAF 71/224 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV59715138; called by muse, mutect2, varscan2
- SETD1A | c.1046C>T p.S349L | Missense Mutation (SNP) | VAF 84/191 reads (44%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.198); catalogued as rs746239302, COSV52690019; called by muse, mutect2, varscan2
- SETD2 | c.3617C>T p.S1206F | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV57449362; called by muse, mutect2, varscan2
- SETDB2 | c.2072G>A p.W691* | Nonsense Mutation (SNP) | VAF 28/74 reads (38%) | catalogued as COSV57904706; called by muse, mutect2, varscan2
- SETX | c.3722C>A p.T1241N | Missense Mutation (SNP) | VAF 40/141 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV56393527; called by muse, mutect2, varscan2
- SIVA1 | c.275G>A p.G92D | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57331909; called by muse, mutect2, varscan2
- SLC22A9 | c.1220G>A p.R407Q | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.918); catalogued as rs760458545, COSV54165823; called by muse, mutect2, varscan2
- SLC9A2 | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 75/248 reads (30%) | SIFT tolerated (0.45); PolyPhen benign (0.035); catalogued as rs61743555, COSV52128997; called by muse, mutect2, varscan2
- SLC9A7 | c.629C>T p.S210F | Missense Mutation (SNP) | VAF 39/134 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs770846350, COSV60381791; called by muse, mutect2, varscan2
- SNCAIP | c.1042G>A p.E348K | Missense Mutation (SNP) | VAF 54/102 reads (53%) | SIFT tolerated (0.09); PolyPhen benign (0.385); catalogued as rs534709742, COSV54401767; called by muse, mutect2, varscan2
- SNTG1 | c.118G>T p.E40* | Nonsense Mutation (SNP) | VAF 38/119 reads (32%) | catalogued as COSV52451211, COSV52468621; called by muse, mutect2, varscan2
- SOWAHA | c.1639C>A p.P547T | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.599); catalogued as COSV66332241; called by muse, mutect2, varscan2
- SPEG | c.4153A>G p.T1385A | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV56678620; called by muse, mutect2
- SPEG | c.9595C>T p.L3199F | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56678634; called by muse, mutect2, varscan2
- SRPX2 | c.865G>A p.E289K | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV65934042; called by muse, mutect2, varscan2
- SRRM2 | c.3781A>G p.K1261E | Missense Mutation (SNP) | VAF 81/151 reads (54%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.112); catalogued as COSV57079815; called by muse, mutect2, varscan2
- STAB1 | c.5821G>A p.G1941S | Missense Mutation (SNP) | VAF 38/65 reads (58%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58742244; called by muse, mutect2, varscan2
- STK31 | c.1477G>A p.E493K | Missense Mutation (SNP) | VAF 38/77 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.115); catalogued as COSV63454655; called by muse, mutect2, varscan2
- SYNE3 | c.2590C>T p.R864C | Missense Mutation (SNP) | VAF 38/126 reads (30%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.634); catalogued as rs141951711; called by muse, mutect2, varscan2
- SYT15 | c.257G>A p.R86Q | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT tolerated (0.59); PolyPhen benign (0.005); catalogued as rs782578619, COSV65433280; called by mutect2, varscan2
- TACC1 | c.281C>T p.S94L | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV52528192; called by muse, mutect2, varscan2
- TBC1D32 | c.922C>T p.R308C | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752518415, COSV51551662; called by muse, mutect2, varscan2
- TBC1D8B | c.274G>A p.D92N | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.11); catalogued as COSV52180963, COSV52182956; called by muse, mutect2, varscan2
- TLCD3B | c.449G>A p.W150* | Nonsense Mutation (SNP) | VAF 47/119 reads (39%) | catalogued as COSV54228053; called by muse, mutect2, varscan2
- TMEM121B | c.1634C>T p.P545L | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.013); catalogued as rs1383742263, COSV58898428; called by muse, mutect2, varscan2
- TMEM131 | c.4516C>T p.P1506S | Missense Mutation (SNP) | VAF 33/136 reads (24%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0.001); catalogued as COSV51784890; called by muse, mutect2, varscan2
- TMTC3 | c.1847C>T p.A616V | Missense Mutation (SNP) | VAF 35/123 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57126103; called by muse, mutect2, varscan2
- TPTE | c.871G>A p.D291N (on ENST00000618007 / NM_199261.4; = p.D273N on NM_199259.4) | Missense Mutation (SNP) | VAF 26/266 reads (10%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.493); catalogued as rs373367615; called by muse, mutect2, varscan2
- TPTE2 | c.1257G>A p.M419I (on ENST00000400230 / NM_199254.2; = p.M342I on NM_130785.3) | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.065); catalogued as COSV55024620; called by muse, mutect2, varscan2
- TRAV10 | c.110G>A p.G37E | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as rs866953660; called by muse, mutect2, varscan2
- TTC26 | c.14G>A p.R5K | Missense Mutation (SNP) | VAF 39/70 reads (56%) | SIFT tolerated (0.13); PolyPhen benign (0.05); catalogued as COSV58272903; called by muse, mutect2, varscan2
- TTN | c.68077G>A p.D22693N (on ENST00000591111; = p.D15269N on NM_003319.4) | Missense Mutation (SNP) | VAF 14/55 reads (25%) | PolyPhen benign (0.043); catalogued as COSV60164171, COSV60303272; called by muse, mutect2, varscan2
- TTN | c.58617G>A p.M19539I (on ENST00000591111; = p.M12115I on NM_003319.4) | Missense Mutation (SNP) | VAF 16/45 reads (36%) | PolyPhen benign (0.003); catalogued as COSV60303330; called by muse, mutect2, varscan2
- TTN | c.39166G>A p.E13056K (on ENST00000591111; = p.E5632K on NM_003319.4) | Missense Mutation (SNP) | VAF 25/120 reads (21%) | PolyPhen probably damaging (0.994); catalogued as rs1356852922, COSV59905230; called by muse, mutect2, varscan2
- TUBGCP6 | c.2494C>T p.P832S | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.73); PolyPhen benign (0.039); catalogued as COSV50542148; called by muse, mutect2, varscan2
- UPF3B | c.409C>G p.Q137E | Missense Mutation (SNP) | VAF 45/132 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV52231400; called by muse, mutect2, varscan2
- USF3 | c.5923C>T p.P1975S | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as COSV57072043, COSV57072205; called by muse, mutect2, varscan2
- USF3 | c.3491C>T p.P1164L | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.599); catalogued as COSV57076838; called by muse, mutect2, varscan2
- USP25 | c.503C>T p.P168L | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53486956; called by muse, mutect2, varscan2
- UVSSA | c.734C>T p.P245L | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.75); PolyPhen benign (0.001); catalogued as rs764512705, COSV66230315; called by muse, mutect2, varscan2
- VEGFC | c.234G>A p.W78* | Nonsense Mutation (SNP) | VAF 12/23 reads (52%) | catalogued as COSV54605402; called by muse, mutect2, varscan2
- XRCC2 | c.440T>C p.I147T | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.665); catalogued as COSV63771058; called by muse, mutect2, varscan2
- ZBTB39 | c.83C>T p.T28I | Missense Mutation (SNP) | VAF 57/160 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.852); catalogued as COSV55630703; called by muse, mutect2, varscan2
- ZKSCAN1 | c.551C>T p.S184F | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.445); catalogued as COSV60874736; called by muse, mutect2, varscan2
- ZMYND8 | c.2269C>T p.P757S (on ENST00000311275 / NM_001363741.2; = p.P777S on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/151 reads (26%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.015); catalogued as rs769574932, COSV53697250; called by muse, mutect2, varscan2
- ZNF154 | c.958C>T p.H320Y | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.029); catalogued as COSV70745404; called by muse, mutect2, varscan2
- ZNF232 | c.559G>A p.G187R | Missense Mutation (SNP) | VAF 58/129 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.176); catalogued as COSV51504216; called by muse, mutect2, varscan2
- ZNF474 | c.803C>T p.P268L | Missense Mutation (SNP) | VAF 28/47 reads (60%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV56946792; called by muse, mutect2, varscan2
- ZNF804A | c.1798A>T p.K600* | Nonsense Mutation (SNP) | VAF 51/142 reads (36%) | catalogued as COSV56468520; called by muse, mutect2, varscan2
- ZNRF4 | c.334G>A p.D112N | Missense Mutation (SNP) | VAF 48/84 reads (57%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.672); catalogued as COSV55773410; called by muse, mutect2, varscan2
- ANKRD35 | c.845A>T p.E282V | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- ANKRD35 | c.844G>A p.E282K | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- ANXA2 | c.588G>A p.R196= | Splice Region (SNP) | VAF 15/23 reads (65%) | called by muse, mutect2, varscan2
- ASXL3 | c.3845del p.L1282* | Frame Shift Del (DEL) | VAF 25/103 reads (24%) | called by mutect2, pindel, varscan2
- GRIN3A | c.2214_2217dup p.W740Mfs*33 | Frame Shift Ins (INS) | VAF 11/44 reads (25%) | called by pindel, varscan2
- IGHV1-18 | c.203G>A p.G68E | Missense Mutation (SNP) | VAF 74/248 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.728); called by muse, mutect2, varscan2
- KIF26B | c.2837C>T p.P946L | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- MDM2 | c.118C>T p.L40F | Missense Mutation (SNP) | VAF 65/195 reads (33%) | SIFT tolerated (0.42); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- MUC17 | c.12316C>T p.P4106S | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- NKAPL | c.160C>T p.P54S | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PNRC2 | c.120del p.H40Qfs*87 | Frame Shift Del (DEL) | VAF 14/74 reads (19%) | called by mutect2, pindel*, varscan2
- TRAV5 | c.109G>A p.D37N | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.37); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- TRBV5-1 | c.65G>A p.G22E | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.533); called by muse, mutect2
- VIRMA | c.5098_5100delinsAT p.F1700Ifs*136 | Frame Shift Del (DEL) | VAF 34/133 reads (26%) | called by pindel, varscan2*
- ZMYND8 | c.2270C>T p.P757L (on ENST00000311275 / NM_001363741.2; = p.P777L on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/151 reads (26%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZNF407 | c.1401_1412del p.Q467_T470del | In Frame Del (DEL) | VAF 24/69 reads (35%) | called by mutect2, pindel, varscan2
- ZNFX1 | c.3194C>T p.P1065L | Missense Mutation (SNP) | VAF 37/152 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNFX1 | c.3193C>T p.P1065S | Missense Mutation (SNP) | VAF 38/155 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ABCC11 | c.2652C>T p.F884= | Silent (SNP) | VAF 30/66 reads (45%) | catalogued as COSV62325555; called by muse, mutect2, varscan2
- ACER2 | c.489C>T p.I163= | Silent (SNP) | VAF 17/44 reads (39%) | catalogued as rs141700425; called by muse, mutect2, varscan2
- ADAMTS17 | c.2652G>A p.R884= | Silent (SNP) | VAF 33/59 reads (56%) | catalogued as COSV51492177; called by muse, mutect2, varscan2
- ADAT1 | c.1011C>T p.S337= | Silent (SNP) | VAF 26/59 reads (44%) | called by muse, mutect2, varscan2
- ADCY2 | c.283C>T p.L95= | Silent (SNP) | VAF 19/149 reads (13%) | catalogued as rs1482619146, COSV57896218; called by muse, mutect2, varscan2
- ADGRF4 | c.1767T>C p.I589= | Silent (SNP) | VAF 62/166 reads (37%) | catalogued as COSV51956936; called by muse, mutect2, varscan2
- AFF2 | c.2847C>T p.I949= | Silent (SNP) | VAF 22/64 reads (34%) | catalogued as COSV53996504; called by muse, mutect2, varscan2
- ALDH1L1 | c.339C>T p.H113= | Silent (SNP) | VAF 3/14 reads (21%) | catalogued as COSV56418666; called by muse, mutect2
- ATP13A5 | c.2754C>T p.I918= | Silent (SNP) | VAF 45/109 reads (41%) | catalogued as rs768145622, COSV60874569; called by muse, mutect2, varscan2
- BCO2 | c.1716C>T p.F572= | Silent (SNP) | VAF 16/38 reads (42%) | catalogued as COSV63063560; called by muse, mutect2, varscan2
- BTN1A1 | c.639G>A p.A213= | Silent (SNP) | VAF 44/122 reads (36%) | catalogued as rs756803845, COSV55069139; called by muse, mutect2, varscan2
- C1orf94 | c.735G>A p.L245= (on ENST00000488417 / NM_001134734.2; = p.L55= on NM_032884.5) | Silent (SNP) | VAF 28/66 reads (42%) | catalogued as COSV64915500; called by muse, mutect2, varscan2
- C6orf118 | c.576C>T p.S192= | Silent (SNP) | VAF 24/61 reads (39%) | catalogued as COSV57818534; called by muse, mutect2, varscan2
- CAMLG | c.846C>T p.I282= | Silent (SNP) | VAF 19/47 reads (40%) | catalogued as COSV51805601; called by muse, mutect2, varscan2
- CAPN9 | c.477C>T p.F159= | Silent (SNP) | VAF 18/58 reads (31%) | catalogued as rs1259542731, COSV55239136; called by muse, varscan2
- CD53 | c.618G>A p.L206= | Silent (SNP) | VAF 23/85 reads (27%) | catalogued as COSV54762932; called by muse, mutect2, varscan2
- CDH20 | c.1482C>T p.F494= | Silent (SNP) | VAF 56/153 reads (37%) | catalogued as COSV53016850, COSV99404208; called by muse, mutect2, varscan2
- CDHR3 | c.1395C>T p.S465= | Silent (SNP) | VAF 13/32 reads (41%) | catalogued as rs1367824365, COSV58421173; called by muse, mutect2, varscan2
- CDK16 | c.129C>T p.D43= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as COSV52093705; called by muse, mutect2, varscan2
- CEP104 | c.2289C>A p.S763= | Silent (SNP) | VAF 31/100 reads (31%) | catalogued as COSV65519388; called by muse, mutect2, varscan2
- CHIA | c.1152G>A p.K384= (on ENST00000343320; = p.K276= on NM_021797.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 19/68 reads (28%) | catalogued as COSV58477792; called by muse, mutect2, varscan2
- CLCN5 | c.2094C>T p.I698= | Silent (SNP) | VAF 23/74 reads (31%) | catalogued as rs782621146, COSV100260374, COSV56585534; called by muse, mutect2, varscan2
- CNTNAP1 | c.192G>A p.R64= | Silent (SNP) | VAF 42/89 reads (47%) | called by muse, mutect2, varscan2
- COL5A1 | c.5406C>T p.I1802= | Silent (SNP) | VAF 9/57 reads (16%) | catalogued as rs766748232, COSV65668566; called by muse, mutect2, varscan2
- CR2 | c.990G>A p.Q330= | Silent (SNP) | VAF 12/29 reads (41%) | catalogued as COSV65509441; called by muse, mutect2, varscan2
- CTSF | c.951C>T p.S317= | Silent (SNP) | VAF 6/58 reads (10%) | catalogued as rs753334318; called by mutect2, varscan2
- DEF6 | c.552C>T p.F184= | Silent (SNP) | VAF 26/107 reads (24%) | catalogued as COSV100359404; called by muse, mutect2, varscan2
- DEF6 | c.553C>T p.L185= | Silent (SNP) | VAF 27/107 reads (25%) | catalogued as COSV57354284; called by muse, mutect2, varscan2
- DNAH7 | c.3213C>T p.F1071= | Silent (SNP) | VAF 32/102 reads (31%) | catalogued as COSV56766131, COSV56770110; called by muse, mutect2, varscan2
- DNAH8 | c.10800G>A p.E3600= | Silent (SNP) | VAF 20/85 reads (24%) | catalogued as COSV59436868, COSV59447129; called by muse, mutect2, varscan2
- DNAJC16 | c.1390C>T p.L464= | Silent (SNP) | VAF 103/252 reads (41%) | catalogued as COSV65449393; called by muse, mutect2, varscan2
- DNMT3L | c.375G>A p.L125= | Silent (SNP) | VAF 13/53 reads (25%) | catalogued as COSV54265824; called by muse, mutect2, varscan2
- ENDOD1 | c.1236C>T p.L412= | Silent (SNP) | VAF 51/92 reads (55%) | catalogued as rs752589406, COSV53591123; called by muse, mutect2, varscan2
- ENGASE | c.1974C>T p.V658= | Silent (SNP) | VAF 27/63 reads (43%) | catalogued as COSV56137645; called by muse, mutect2, varscan2
- ENPP7 | c.585C>T p.F195= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as rs782420570, COSV60387701; called by mutect2, varscan2
- ERBIN | c.3222C>T p.I1074= | Silent (SNP) | VAF 46/98 reads (47%) | catalogued as COSV52326058; called by muse, mutect2, varscan2
- ETFRF1 | c.120C>T p.F40= | Silent (SNP) | VAF 24/62 reads (39%) | catalogued as COSV61600125; called by muse, mutect2
- FAM47B | c.669C>T p.L223= | Silent (SNP) | VAF 24/71 reads (34%) | catalogued as rs1293129315, COSV61456511; called by muse, mutect2, varscan2
- FAM71A | c.1500G>A p.K500= | Silent (SNP) | VAF 42/117 reads (36%) | catalogued as COSV54237048; called by muse, mutect2, varscan2
- FCGBP | c.7095G>A p.S2365= | Silent (SNP) | VAF 26/156 reads (17%) | catalogued as rs1458831392; called by muse, mutect2, varscan2
- FGD3 | c.435G>A p.K145= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as COSV61599655; called by muse, mutect2, varscan2
- FHOD3 | c.387C>T p.S129= | Silent (SNP) | VAF 7/15 reads (47%) | catalogued as rs774533065, COSV57186785; called by muse, mutect2, varscan2
- FLNC | c.3510C>T p.V1170= | Silent (SNP) | VAF 11/74 reads (15%) | catalogued as rs745571747, COSV57963723; ClinVar: likely benign; called by muse, mutect2, varscan2
- GMPR | c.462T>C p.I154= | Silent (SNP) | VAF 45/112 reads (40%) | catalogued as COSV52475157; called by muse, mutect2, varscan2
- GREM2 | c.264G>A p.R88= | Silent (SNP) | VAF 15/62 reads (24%) | catalogued as COSV58952355, COSV58956697; called by muse, mutect2, varscan2
- GRM3 | c.2046C>T p.F682= | Silent (SNP) | VAF 21/74 reads (28%) | catalogued as COSV64478679, COSV64480448; called by muse, mutect2, varscan2
- GXYLT1 | c.660C>T p.I220= | Silent (SNP) | VAF 23/84 reads (27%) | catalogued as COSV55142048; called by muse, mutect2, varscan2
- H6PD | c.819C>T p.T273= | Silent (SNP) | VAF 18/49 reads (37%) | catalogued as rs1454196388, COSV66232163; called by muse, mutect2, varscan2
- HDAC8 | c.783C>T p.V261= | Silent (SNP) | VAF 28/79 reads (35%) | catalogued as COSV65268579; called by muse, mutect2, varscan2
- HTR2B | c.735G>A p.Q245= | Silent (SNP) | VAF 23/83 reads (28%) | catalogued as rs757704130, COSV51450603; called by muse, mutect2, varscan2
- HUWE1 | c.1434G>A p.K478= | Silent (SNP) | VAF 60/182 reads (33%) | catalogued as rs1557018798, COSV53362035; called by muse, mutect2, varscan2
- HYAL4 | c.609C>T p.I203= | Silent (SNP) | VAF 58/122 reads (48%) | catalogued as COSV56140194; called by muse, mutect2, varscan2
- ITPR3 | c.2853G>A p.L951= | Silent (SNP) | VAF 25/87 reads (29%) | catalogued as COSV65414363; called by muse, mutect2, varscan2
- KCNK10 | c.564C>T p.A188= | Silent (SNP) | VAF 43/149 reads (29%) | catalogued as COSV56651532; called by muse, mutect2, varscan2
- KCNQ2 | c.426C>T p.F142= | Silent (SNP) | VAF 18/50 reads (36%) | catalogued as rs780770793, COSV60438733; ClinVar: likely benign; called by muse, mutect2, varscan2
- KLHL20 | c.942C>T p.I314= | Silent (SNP) | VAF 16/62 reads (26%) | catalogued as COSV52944753; called by muse, mutect2, varscan2
- KLHL6 | c.1839G>A p.R613= | Silent (SNP) | VAF 27/75 reads (36%) | catalogued as COSV58069111; called by muse, mutect2, varscan2
- LEPR | c.528C>T p.P176= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as COSV100756167; called by muse, mutect2, varscan2
- LILRA6 | c.924C>T p.A308= | Silent (SNP) | VAF 24/149 reads (16%) | called by muse, mutect2
- LTF | c.1524C>T p.F508= | Silent (SNP) | VAF 58/133 reads (44%) | catalogued as rs1317156236, COSV51611709; called by muse, mutect2, varscan2
- MAP3K5 | c.2382C>T p.L794= | Silent (SNP) | VAF 21/83 reads (25%) | catalogued as rs1235423771, COSV62891566; called by muse, mutect2, varscan2
- MAPK8IP3 | c.2667C>T p.S889= | Silent (SNP) | VAF 21/46 reads (46%) | catalogued as COSV51726479; called by muse, varscan2
- MCTP2 | c.210G>A p.G70= | Silent (SNP) | VAF 66/97 reads (68%) | catalogued as rs756383264, COSV59149634; called by muse, mutect2, varscan2
- MED23 | c.1320C>T p.N440= | Silent (SNP) | VAF 27/67 reads (40%) | catalogued as COSV63436753; called by muse, mutect2, varscan2
- MFSD5 | c.114C>T p.F38= | Silent (SNP) | VAF 69/163 reads (42%) | catalogued as rs1321238255, COSV61566141; called by muse, mutect2, varscan2
- MLN | c.78C>T p.F26= | Silent (SNP) | VAF 50/159 reads (31%) | catalogued as COSV56475844; called by muse, mutect2, varscan2
- MPEG1 | c.1449C>T p.F483= | Silent (SNP) | VAF 38/83 reads (46%) | catalogued as rs1269164567, COSV57094517, COSV99914848; called by muse, mutect2, varscan2
- MS4A8 | c.288G>A p.G96= | Silent (SNP) | VAF 18/143 reads (13%) | catalogued as COSV55755614; called by muse, mutect2, varscan2
- MUC5B | c.13152C>T p.S4384= | Silent (SNP) | VAF 43/72 reads (60%) | catalogued as COSV71592091; called by muse, mutect2, varscan2
- MYL3 | c.54G>A p.K18= | Silent (SNP) | VAF 29/52 reads (56%) | catalogued as COSV52768175; called by muse, mutect2, varscan2
- NCKAP1L | c.1143C>T p.T381= | Silent (SNP) | VAF 45/115 reads (39%) | catalogued as COSV53211660; called by muse, mutect2, varscan2
- NKAIN2 | c.138C>T p.I46= | Silent (SNP) | VAF 29/93 reads (31%) | catalogued as rs746180378, COSV63679539; called by muse, mutect2, varscan2
- NLRP2 | c.2757G>A p.K919= | Silent (SNP) | VAF 40/159 reads (25%) | catalogued as COSV54759628; called by muse, mutect2, varscan2
- NNT | c.801G>A p.K267= | Silent (SNP) | VAF 37/150 reads (25%) | catalogued as COSV52929029; called by muse, mutect2, varscan2
- OR10K1 | c.666C>T p.I222= | Silent (SNP) | VAF 27/88 reads (31%) | catalogued as COSV56873848, COSV99193881; called by muse, varscan2
- OR10Z1 | c.81C>T p.L27= | Silent (SNP) | VAF 32/112 reads (29%) | catalogued as COSV63523770, COSV63524947, COSV63526801; called by muse, mutect2, varscan2
- OR1F1 | c.321C>T p.F107= | Silent (SNP) | VAF 63/131 reads (48%) | catalogued as rs375366387; called by muse, mutect2, varscan2
- OR1L8 | c.889C>T p.L297= | Silent (SNP) | VAF 42/101 reads (42%) | catalogued as COSV59187242; called by muse, mutect2, varscan2
- OR1L8 | c.744G>A p.V248= | Silent (SNP) | VAF 23/43 reads (53%) | catalogued as COSV59187253; called by muse, mutect2, varscan2
- OR2T2 | c.39C>T p.F13= | Silent (SNP) | VAF 40/245 reads (16%) | catalogued as rs779374477, COSV61617823; called by muse, mutect2, varscan2
- OR4C15 | c.1056G>A p.R352= (on ENST00000314644; = p.R298= on NM_001001920.2) | Silent (SNP) | VAF 27/45 reads (60%) | catalogued as COSV58955239; called by muse, mutect2, varscan2
- OR4C3 | c.327G>A p.E109= | Silent (SNP) | VAF 54/157 reads (34%) | catalogued as COSV60585982; called by muse, mutect2, varscan2
- OR9A4 | c.705G>A p.R235= | Silent (SNP) | VAF 29/166 reads (17%) | catalogued as rs143629932, COSV71885478; called by muse, mutect2, varscan2
- P2RX6 | c.663C>T p.D221= | Silent (SNP) | VAF 57/193 reads (30%) | catalogued as COSV60385924; called by muse, mutect2, varscan2
- PCDHB11 | c.15G>A p.G5= | Silent (SNP) | VAF 18/35 reads (51%) | catalogued as rs546487034, COSV53383197; called by muse, mutect2, varscan2
- PIAS2 | c.840T>G p.S280= | Silent (SNP) | VAF 25/106 reads (24%) | catalogued as COSV61344950; called by muse, mutect2, varscan2
- PID1 | c.660G>A p.R220= (on ENST00000354069 / NM_001330156.1; = p.R218= on NM_017933.5) | Silent (SNP) | VAF 47/119 reads (39%) | catalogued as rs140609082; called by muse, mutect2, varscan2
- PKP1 | c.1977C>T p.S659= | Silent (SNP) | VAF 76/207 reads (37%) | catalogued as rs1258320654, COSV55824864; called by muse, mutect2, varscan2
- PLCZ1 | c.1377G>A p.L459= | Silent (SNP) | VAF 20/60 reads (33%) | catalogued as COSV56857995; called by muse, mutect2, varscan2
- PLIN5 | c.357G>A p.K119= | Silent (SNP) | VAF 32/63 reads (51%) | catalogued as COSV67851032; called by muse, mutect2, varscan2
- PLXNA3 | c.4140G>A p.T1380= | Silent (SNP) | VAF 14/57 reads (25%) | catalogued as rs782808584, COSV63755483; called by muse, mutect2, varscan2
- PNMA8B | c.115C>T p.L39= | Silent (SNP) | VAF 41/93 reads (44%) | catalogued as COSV66537617; called by muse, mutect2, varscan2
- PRDM2 | c.3186T>G p.S1062= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as COSV52454616; called by muse, mutect2, varscan2
- PRKDC | c.954C>T p.S318= | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as COSV58061904; called by muse, mutect2, varscan2
- PRKX | c.999C>T p.F333= | Silent (SNP) | VAF 16/47 reads (34%) | catalogued as rs762522125, COSV53324103; called by muse, mutect2, varscan2
- PTPRN2 | c.1275G>A p.R425= | Silent (SNP) | VAF 77/163 reads (47%) | catalogued as COSV67056581; called by muse, mutect2, varscan2
- PURG | c.315G>A p.L105= | Silent (SNP) | VAF 29/92 reads (32%) | catalogued as COSV53306439; called by muse, mutect2, varscan2
- RERE | c.4083C>T p.P1361= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as rs1248350939, COSV61949517; called by muse, mutect2, varscan2
- RHEX | c.399G>A p.E133= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as COSV58981855; called by muse, mutect2, varscan2
- ROS1 | c.540C>T p.S180= | Silent (SNP) | VAF 30/99 reads (30%) | catalogued as COSV63861016; called by muse, mutect2, varscan2
- RYR1 | c.3073C>T p.L1025= | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as COSV62109046; called by muse, varscan2
- SF3A1 | c.1431C>T p.F477= | Silent (SNP) | VAF 52/168 reads (31%) | catalogued as rs186048479; called by muse, mutect2, varscan2
- SKIV2L | c.2133C>T p.P711= | Silent (SNP) | VAF 82/283 reads (29%) | catalogued as COSV61714943; called by muse, mutect2, varscan2
- SLC15A2 | c.912C>T p.F304= | Silent (SNP) | VAF 62/220 reads (28%) | catalogued as COSV55200508; called by muse, mutect2, varscan2
- SLC17A1 | c.966A>C p.S322= | Silent (SNP) | VAF 17/62 reads (27%) | catalogued as COSV55081869; called by muse, mutect2, varscan2
- SLC17A8 | c.159G>A p.R53= | Silent (SNP) | VAF 68/200 reads (34%) | catalogued as COSV100035006, COSV60126339; called by muse, mutect2, varscan2
- SLC26A4 | c.1665C>T p.F555= | Silent (SNP) | VAF 25/81 reads (31%) | catalogued as COSV55919641; called by muse, mutect2, varscan2
- SPRED1 | c.240C>T p.L80= | Silent (SNP) | VAF 58/108 reads (54%) | catalogued as COSV54438691; called by muse, mutect2, varscan2
- SRGAP1 | c.2308C>T p.L770= | Silent (SNP) | VAF 44/107 reads (41%) | catalogued as rs771044430, COSV61902696; called by muse, mutect2, varscan2
- SSTR1 | c.21C>T p.A7= | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as COSV57457454; called by muse, varscan2
- STAC3 | c.558C>T p.I186= | Silent (SNP) | VAF 87/222 reads (39%) | catalogued as COSV60414769; called by muse, mutect2, varscan2
- SULT1C2 | c.340C>T p.L114= | Silent (SNP) | VAF 50/163 reads (31%) | catalogued as COSV52266867; called by muse, mutect2, varscan2
- SVOPL | c.1278G>A p.T426= (on ENST00000419765; = p.T274= on NM_174959.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/32 reads (44%) | catalogued as rs759829104, COSV55989614, COSV55994466; called by muse, mutect2, varscan2
- SYCP1 | c.1453T>C p.L485= | Silent (SNP) | VAF 12/53 reads (23%) | catalogued as rs747506634, COSV65700581; called by muse, mutect2, varscan2
- SYCP2L | c.1851C>T p.S617= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as COSV51657052; called by muse, mutect2, varscan2
- SYNRG | c.3696C>T p.S1232= | Silent (SNP) | VAF 33/68 reads (49%) | catalogued as rs748349406; called by muse, mutect2, varscan2
- TENM1 | c.6867G>A p.S2289= | Silent (SNP) | VAF 62/180 reads (34%) | catalogued as rs766264450, COSV64424619; called by muse, mutect2, varscan2
- TGIF2LX | c.345G>A p.Q115= | Silent (SNP) | VAF 52/129 reads (40%) | catalogued as rs138727889, COSV52215071, COSV52215552; called by muse, mutect2, varscan2
- TMEM43 | c.483C>T p.F161= | Silent (SNP) | VAF 18/35 reads (51%) | catalogued as rs772842801, COSV60145835; called by muse, mutect2, varscan2
- TNN | c.252C>T p.I84= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as COSV53434277; called by muse, mutect2, varscan2
- TRAV16 | c.156C>T p.L52= | Silent (SNP) | VAF 6/24 reads (25%) | called by muse, mutect2
- TRIM71 | c.12C>T p.F4= | Silent (SNP) | VAF 15/29 reads (52%) | catalogued as rs1480818423, COSV67472531; called by muse, mutect2, varscan2
- TRMT44 | c.1377C>T p.S459= | Silent (SNP) | VAF 33/66 reads (50%) | catalogued as COSV67664852; called by muse, mutect2, varscan2
- TSR2 | c.453G>A p.T151= | Silent (SNP) | VAF 11/27 reads (41%) | catalogued as rs751228990, COSV64308615; called by muse, mutect2, varscan2
- TTF1 | c.438G>A p.Q146= | Silent (SNP) | VAF 41/117 reads (35%) | catalogued as COSV57506996; called by muse, mutect2, varscan2
- TTN | c.67068C>T p.F22356= (on ENST00000591111; = p.F14932= on NM_003319.4) | Silent (SNP) | VAF 22/94 reads (23%) | catalogued as COSV60303304; called by muse, mutect2, varscan2
- TTN | c.12345C>T p.I4115= (on ENST00000591111; = p.I4069= on NM_003319.4) | Silent (SNP) | VAF 30/119 reads (25%) | catalogued as rs1195699934; ClinVar: likely benign; called by muse, mutect2, varscan2
- TULP1 | c.492C>T p.G164= | Silent (SNP) | VAF 43/119 reads (36%) | catalogued as COSV57693756; called by muse, mutect2, varscan2
- TYK2 | c.753C>T p.S251= | Silent (SNP) | VAF 8/17 reads (47%) | catalogued as rs1188853680, COSV53391495; called by muse, mutect2, varscan2
- UBLCP1 | c.267C>T p.P89= | Silent (SNP) | VAF 29/77 reads (38%) | catalogued as COSV57144659; called by muse, mutect2, varscan2
- USP28 | c.2391G>A p.G797= | Silent (SNP) | VAF 28/57 reads (49%) | catalogued as COSV50185693; called by muse, mutect2, varscan2
- VWA5A | c.2238G>A p.E746= | Silent (SNP) | VAF 25/60 reads (42%) | catalogued as COSV64414297; called by muse, mutect2, varscan2
- ZAN | c.7347G>A p.R2449= | Silent (SNP) | VAF 33/126 reads (26%) | catalogued as COSV61809478; called by muse, mutect2, varscan2
- ZFR | c.1602T>G p.A534= | Silent (SNP) | VAF 12/60 reads (20%) | catalogued as COSV54057281; called by muse, mutect2, varscan2
- ZFYVE1 | c.258G>A p.Q86= | Silent (SNP) | VAF 92/255 reads (36%) | catalogued as COSV59612868; called by muse, mutect2, varscan2
- ZMYM3 | c.3039C>T p.F1013= | Silent (SNP) | VAF 19/66 reads (29%) | catalogued as rs369937936, COSV58740484; called by muse, mutect2, varscan2
- ZNF775 | c.1536C>T p.S512= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as COSV61614240; called by muse, mutect2
- ATG16L1 | c.954+1141C>T | Intron (SNP) | VAF 36/91 reads (40%) | catalogued as COSV100731189; called by muse, mutect2, varscan2
- CACNA1D | c.1220+658C>T | Intron (SNP) | VAF 28/67 reads (42%) | catalogued as rs750588563, COSV55448511, COSV55469863; called by muse, mutect2, varscan2
- DEFB110 | c.*2G>A | 3'UTR (SNP) | VAF 7/17 reads (41%) | catalogued as rs144223291; called by muse, mutect2, varscan2
- FOLH1B | n.1357C>T | RNA (SNP) | VAF 29/69 reads (42%) | called by muse, mutect2, varscan2
- KCNIP4 | c.62-421179G>A | Intron (SNP) | VAF 27/43 reads (63%) | catalogued as COSV66182173; called by muse, mutect2, varscan2
- MAGEA5 | n.54C>T | RNA (SNP) | VAF 51/143 reads (36%) | catalogued as rs985321563; called by muse, mutect2, varscan2
- METTL24 | c.*1G>A | 3'UTR (SNP) | VAF 33/141 reads (23%) | catalogued as COSV100133069; called by muse, mutect2, varscan2
- MS4A10 | c.*2G>A | 3'UTR (SNP) | VAF 6/54 reads (11%) | catalogued as COSV100382163, COSV57632391; called by muse, varscan2
- PDGFD | c.125-36708G>A | Intron (SNP) | VAF 53/96 reads (55%) | catalogued as COSV56392262; called by muse, mutect2, varscan2
- SEPTIN5 | c.55-1049G>A | Intron (SNP) | VAF 11/38 reads (29%) | catalogued as COSV100820348; called by muse, mutect2, varscan2
- SLC48A1 | c.*39G>A | 3'UTR (SNP) | VAF 33/121 reads (27%) | catalogued as COSV99315289; called by muse, mutect2, varscan2
- STMP1 | chr7:135660110 G>A | 5'Flank (SNP) | VAF 22/128 reads (17%) | called by muse, mutect2, varscan2
- TTN | c.10361-4005G>A | Intron (SNP) | VAF 26/66 reads (39%) | catalogued as COSV100620343, COSV100625077; called by muse, mutect2, varscan2
